Somatic mutation profile of tumor specimen TCGA-P8-A5KD-01A (aliquot TCGA-P8-A5KD-01A-11D-A35D-08) from TCGA case TCGA-P8-A5KD, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 35.5 years (12,954 days).
Specimen TCGA-P8-A5KD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 733d58ae-475c-4806-8969-d5624a4f1d82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P8-A5KD-10A (Blood Derived Normal), aliquot TCGA-P8-A5KD-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb7caf4a-dd4d-49c3-a00f-4f56fa6626a3

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 52/106 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DNAH17 | c.9253C>T p.Q3085* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- PRG4 | c.559_560dup p.N187Kfs*15 | Frame Shift Ins (INS) | VAF 28/90 reads (31%) | called by pindel, varscan2
- TBC1D2 | c.2726C>G p.S909C (on ENST00000465784 / NM_001267571.2; = p.S898C on NM_018421.4) | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- ACOT12 | c.591C>T p.H197= | Silent (SNP) | VAF 89/250 reads (36%) | catalogued as rs149420016; called by muse, mutect2, varscan2
- NISCH | c.2334G>T p.L778= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
